Gene-level copy-number profile of tumor specimen TCGA-CV-7437-01A from TCGA case TCGA-CV-7437, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 77.3 years (28,221 days).
Specimen TCGA-CV-7437-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.f4980da7-ad80-4449-9a5a-f2d7fc3c4691.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7437-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fca43b90-8d53-47b4-9a07-59774210f25f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,860; copy number 2: 32,305; copy number 3: 16,914; copy number 4: 5,532; copy number 5: 2,193; copy number 6: 91; copy number 9: 273; copy number 10: 647; copy number 14: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7437-01A-21D-2128-01): tumor purity 0.65, ploidy 2.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes: Y_RNA, RNU6-904P, RPS16P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,172 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–121,580,524, 78 genes, copy number 5 (broad region; genes not listed).
- chr2:38,814–64,019,428, 1,034 genes, copy number 5 (broad region; genes not listed).
- chr3:146,909,685–198,222,513, 915 genes, copy number 9–14 (broad region; genes not listed).
- chr7:4,130,181–16,645,817, 189 genes, copy number 5 (broad region; genes not listed).
- chr7:67,627,831–68,319,676, 10 genes, copy number 5: MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3.
- chr8:53,225,724–55,081,909, 35 genes, copy number 5 (within-gene range 2–5): OPRK1, AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7, RP1, SEC11B, AC090151.1, AC084834.1.
- chr8:55,135,203–55,164,727, 2 genes, copy number 5: AC022679.2, AC022679.1.
- chr11:39,873,782–41,459,773, 7 genes, copy number 9 (within-gene range 4–9): AC021749.1, AC021820.1, AC080100.1, LRRC4C, Y_RNA, AC090720.1, RNU6-365P.
- chr12:66,767–30,996,602, 761 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:23,500,905–27,290,492, 70 genes, copy number 5–6 (broad region; genes not listed).
- chr18:20,946,906–23,662,911, 60 genes, copy number 5 (within-gene range 2–5): ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29.
- chr18:39,622,123–40,247,367, 11 genes, copy number 5: MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1.

Autosomal genes at a single copy (total copy number 1): 899. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
